Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A6BN, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A6BN-01A (Primary Tumor).

[page 1 of 2]
THIS IS A CONFIDENTIAL AND PRIVILEGED COMMUNICATION
PLEASE DISPOSE OF PAPER COPIES APPROPRIATELY

Printed by:

Name: [REDACTED]
Test Name: F/S PLEURAL TUMOR(MASS)
Ordered By:

Age:
Test Date:

COLLECTION DATE:
SPECIMEN NUMBER: [REDACTED]

SPECIMENS:
1. F/S PLEURAL TUMOR
2. MASS

ICD-O.3
Mesothelioma, epithelioid NOS
9052/3
Site Pleura NOS C38.4
Jp 5/16/13

DIAGNOSIS:

1. PLEURA, RIGHT: BIOPSY
- MALIGNANT EPITHELIOID MESOTHELIOMA.
2. PLEURA: BIOPSY
- MALIGNANT EPITHELIOID MESOTHELIOMA.

COMMENT: Immunohistochemical study demonstrates the tumor is positive diffusely for cytokeratin (AE1/AE3) and CK5/6, and focally positive for calretinin and WT1. The tumor is negative for mCEA, Ber-EP4 (rare cells +), and TTF1. The findings support the diagnosis. This case has been reviewed intradepartmentally.

Pathologist

CLINICAL HISTORY AND PRE-OPERATIVE DIAGNOSIS:
Lung mass, right

MACROSCOPIC DESCRIPTION:
The specimen is received in two parts labeled with the patient's name.

1. Part one is received fresh labeled 'pleural tumor'. It consists of three fragments of tan soft tissue that range in size from 0.2 x 0.2 x 0.2 to 1 x 0.4 x 0.2 cm. Entirely submitted for frozen section.
2. Part tow is received fresh labeled with 'pleural tumor'. It consists of one 1.4 x 1.2 x 0.3 cm piece of tan soft tissue. One 0.8 cm tan firm plaque is noted on the surface. The specimen is serially sectioned and entirely submitted.

SUMMARY OF SECTIONS:
1A in toto
2A in toto

[page 2 of 2]
SPECIAL PROCEDURES:

AE1/AE3, Calretinin, WT1, Ber-EP4, mCEA, CK5/6, TTF1

INTRA - OPERATIVE CONSULTATION:

1. Pleural tumor; frozen section

Malignant epithelioid tumor, favor mesothelioma. Results
reported by
back by

Intra-Operative Consultation #1 performed by

Electronically signed

Final Diagnosis performed by

Electronically signed

The electronic signature attests that the named Attending
Pathologist has evaluated the specimen referred to in the signed
section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain
results that use analyte specific reagents.

The tests were developed and their performance characteristics
determined by

They have not been cleared or approved by the US Food and Drug
Administration.

The FDA has determined that such clearance or approval is not
necessary.

Source: NCI Genomic Data Commons file ba68544b-3a59-4ecb-b348-57b9d3bd4a77 (TCGA-MQ-A6BN.7FEC6780-415F-42E4-B996-E091CA424621.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).